Somatic mutation profile of tumor specimen ALCH-B1S7-TTP1-A (aliquot ALCH-B1S7-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1S7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.0 years (24,483 days).
Specimen ALCH-B1S7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e77b4504-d6f5-409c-859c-dff437cecfaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1S7-NB1-A (Blood Derived Normal), aliquot ALCH-B1S7-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eccc043c-4f0d-40c4-9889-d50dceee7672

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Intron 2, RNA 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 54/536 reads (10%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel
- CSMD3 | c.3913C>T p.H1305Y (on ENST00000297405 / NM_001363185.1; = p.H1201Y on NM_052900.3) | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as rs1252386363; called by muse, mutect2, varscan2
- FHAD1 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770643908, COSV58990308; called by muse, mutect2
- KIF2B | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769176818, COSV52126857; called by muse, mutect2, varscan2
- PCDH19 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104371501; called by muse, mutect2
- PPP1R10 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759002084; called by muse, mutect2
- SEC31A | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV52342946; called by muse, mutect2
- SELENOO | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 95/354 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs114904672; called by muse, mutect2, varscan2
- SLC10A2 | c.547A>C p.N183H | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs777528270; called by muse, mutect2
- TRPM6 | c.3881G>T p.R1294I | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62510335, COSV62516046; called by muse, mutect2
- COL18A1 | c.2306C>A p.A769E (on ENST00000359759 / NM_130444.3; = p.A534E on NM_030582.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.078); called by muse, mutect2
- CPSF6 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.407); called by muse, mutect2
- DNAJB1 | c.454_457del p.A152Kfs*31 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel, varscan2
- EP400 | c.8572C>T p.Q2858* | Nonsense Mutation (SNP) | VAF 20/518 reads (4%) | called by muse, mutect2
- FRMD7 | c.1460A>T p.Q487L | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.357); called by muse, mutect2
- GAL | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- GUCY1B1 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LSM12 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAPT | c.2314G>A p.E772K (on ENST00000262410 / NM_001377265.1; = p.E380K on NM_005910.5) | Missense Mutation (SNP) | VAF 22/473 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MFAP3L | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.045); called by muse, mutect2
- MYO3A | c.3628G>C p.E1210Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NEFM | c.2338G>C p.E780Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2
- QARS1 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPATC1L | c.610G>C p.D204H (on ENST00000291672 / NM_001142854.2; = p.D50H on NM_032261.5) | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- TAOK3 | c.1362G>C p.E454D | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TG | c.6449G>A p.G2150E | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USH1C | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 60/533 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- USH2A | c.12044C>A p.T4015N | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- AKAP11 | c.2718T>C p.Y906= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- CACNA1A | c.1038C>T p.I346= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as rs527246699, COSV64191162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM2 | c.249C>T p.F83= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV99746735; called by muse, mutect2, varscan2
- HECW2 | c.3927C>T p.F1309= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV53663251; called by muse, mutect2, varscan2
- RARA | c.336C>T p.F112= | Silent (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- SLC35G4 | c.450G>A p.E150= | Silent (SNP) | VAF 47/504 reads (9%) | catalogued as rs749876957; called by muse, mutect2
- ZER1 | c.1719C>T p.L573= | Silent (SNP) | VAF 59/318 reads (19%) | called by muse, mutect2, varscan2
- CEBPZOS | c.*2+1167A>C | Intron (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- IRF6 | c.509-21C>T | Intron (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- OFCC1 | n.340G>A | RNA (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
